Somatic mutation profile of tumor specimen TCGA-06-0879-01A (aliquot TCGA-06-0879-01A-01D-1492-08) from TCGA case TCGA-06-0879, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.4 years (19,154 days).
Specimen TCGA-06-0879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5f63fb7-7a76-4c0a-87e7-1b8940465a8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0879-10A (Blood Derived Normal), aliquot TCGA-06-0879-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c74c4aa-bae0-47e8-afc8-7fce4b2ed72b

The open-access MAF lists 62 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, RNA 3, Nonsense Mutation 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1359A>C p.E453D | Missense Mutation (SNP) | VAF 38/181 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as CD126701, COSV55944133; called by muse, varscan2
- PIK3CA | c.1365_1379del p.L455_G460delinsF | In Frame Del (DEL) | VAF 26/175 reads (15%) | hotspot (GDC flag); called by pindel, varscan2
- AADACL2 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62930551; called by muse, mutect2, varscan2
- ADCY5 | c.3750G>T p.M1250I | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV59199771; called by muse, mutect2
- AFAP1L1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370079883; called by muse, mutect2, varscan2
- AFF2 | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 135/192 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs782318095, COSV53980006; called by muse, mutect2, varscan2
- AOC1 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs199683372; called by muse, mutect2, varscan2
- AQR | c.3352T>C p.S1118P | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV50033137; called by muse, mutect2, varscan2
- ATP2C1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV60756666; called by muse, mutect2, varscan2
- B3GALT5 | c.717T>G p.I239M | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV58198850; called by muse, mutect2, varscan2
- BRDT | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV62864789, COSV62865101; called by muse, mutect2, varscan2
- CAND1 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 131/337 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV73338593; called by muse, mutect2, varscan2
- CCDC81 | c.1291A>G p.S431G (on ENST00000445632 / NM_001156474.2; = p.S341G on NM_021827.4) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53578561; called by muse, mutect2
- ELAVL1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60966642; called by muse, mutect2, varscan2
- FAT2 | c.10855G>A p.V3619M | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs1405870851, COSV55822890, COSV55824857; called by muse, mutect2
- FBN2 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV52514596; called by muse, mutect2, varscan2
- GALNT2 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64194948; called by muse, mutect2, varscan2
- GLI1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57362262, COSV99954859; called by muse, mutect2, varscan2
- ITPR1 | c.2693G>A p.C898Y (on ENST00000354582; = p.C883Y on NM_002222.7) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56982474; called by muse, mutect2, varscan2
- KEL | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as rs767483672, COSV62335112; called by muse, mutect2, varscan2
- LGALS8 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs775638029, COSV53024728; called by muse, mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by muse, mutect2, varscan2
- MINAR1 | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59583175; called by muse, mutect2, varscan2
- MTUS2 | c.1987G>T p.V663F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV70916903; called by muse, mutect2, varscan2
- NCF2 | c.609G>A p.T203= | Splice Region (SNP) | VAF 123/335 reads (37%) | catalogued as rs147657171, COSV62316343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OSBPL6 | c.2282G>A p.C761Y | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51918464, COSV51930980; called by muse, mutect2, varscan2
- PCDHB13 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs782053306, COSV53394300; called by muse, varscan2
- PCDHB8 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.751); catalogued as rs782235349, COSV50759260, COSV99175201; called by muse, mutect2
- PITPNC1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as rs755116394, COSV55452453; called by muse, mutect2, varscan2
- PLSCR3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1174093729, COSV61171235; called by muse, mutect2, varscan2
- PPP4R4 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 89/260 reads (34%) | catalogued as rs1566680153, COSV58552370; called by muse, mutect2, varscan2
- SCN1A | c.5914A>T p.K1972* (on ENST00000303395 / NM_001202435.3; = p.K1961* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 51/149 reads (34%) | catalogued as rs1553519734, COSV57670774; called by muse, mutect2, varscan2
- SLC6A6 | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62649853; called by muse, mutect2, varscan2
- SLC7A5 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55364579; called by muse, mutect2, varscan2
- TEKT4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782558219, COSV54626009; called by muse, mutect2, varscan2
- TMEM200A | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs140251464; called by muse, mutect2, varscan2
- TPTE | c.1574G>T p.R525I (on ENST00000618007 / NM_199261.4; = p.R507I on NM_199259.4) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs376317057; called by muse, mutect2, varscan2
- TTN | c.8784G>T p.K2928N (on ENST00000591111; = p.K2882N on NM_003319.4) | Missense Mutation (SNP) | VAF 148/460 reads (32%) | PolyPhen possibly damaging (0.743); catalogued as COSV60152966; called by muse, mutect2, varscan2
- ZNF91 | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | PolyPhen benign (0); catalogued as COSV56086513; called by muse, mutect2, varscan2
- ZSWIM2 | c.1784G>C p.S595T | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54575573; called by muse, mutect2, varscan2
- IGLV2-18 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 177/485 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- VN1R5 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ARL11 | c.369G>A p.K123= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV56291272; called by muse, mutect2, varscan2
- CALML5 | c.216G>A p.A72= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as rs1184192900, COSV66702554; called by muse, mutect2
- CFAP54 | c.6342A>G p.R2114= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV61572943; called by muse, mutect2, varscan2
- CHRNG | c.315C>T p.T105= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV51322717; called by muse, mutect2, varscan2
- COL11A1 | c.5127T>C p.N1709= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV100615913, COSV62187637; called by muse, mutect2, varscan2
- DOCK5 | c.3249C>T p.I1083= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs780661201, COSV52402395; called by muse, mutect2, varscan2
- FLG | c.4239C>T p.H1413= | Silent (SNP) | VAF 229/629 reads (36%) | catalogued as rs147032729; called by muse, mutect2, varscan2
- GTSE1 | c.855G>A p.P285= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs749506319, COSV71889093; called by muse, mutect2, varscan2
- MDN1 | c.12498C>T p.S4166= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as rs116003199; called by muse, mutect2, varscan2
- PCDHB3 | c.1710G>A p.A570= | Silent (SNP) | VAF 49/178 reads (28%) | catalogued as COSV50570519; called by muse, varscan2
- PCDHGA9 | c.429C>T p.N143= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as rs1022563452, COSV53899236; called by muse, mutect2, varscan2
- PPP1R12C | c.420G>A p.V140= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV54737452; called by muse, mutect2, varscan2
- PREX1 | c.984G>A p.R328= | Silent (SNP) | VAF 45/243 reads (19%) | catalogued as COSV64253485; called by muse, mutect2, varscan2
- RIMBP2 | c.1149G>A p.T383= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as rs149109982; called by muse, mutect2, varscan2
- SLC6A17 | c.1857A>G p.A619= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV58993322; called by muse, mutect2, varscan2
- SMPDL3B | c.1104G>A p.P368= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs764070368, COSV65855053; called by muse, mutect2, varscan2
- SORCS3 | c.1242C>T p.Y414= | Silent (SNP) | VAF 81/146 reads (55%) | catalogued as rs531557060, COSV63810874; called by muse, mutect2, varscan2
- ARPP19P2 | n.155G>A | RNA (SNP) | VAF 48/150 reads (32%) | catalogued as rs754124555; called by muse, mutect2, varscan2
- MIR509-2 | n.29_30delinsT | RNA (DEL) | VAF 65/209 reads (31%) | called by mutect2*, pindel, varscan2*
- MIR509-3 | n.19C>T | RNA (SNP) | VAF 90/414 reads (22%) | catalogued as rs782329671; called by muse, mutect2, varscan2
